Somatic mutation profile of tumor specimen TCGA-ES-A2HS-01A (aliquot TCGA-ES-A2HS-01A-11D-A183-10) from TCGA case TCGA-ES-A2HS, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.1 years (29,268 days).
Specimen TCGA-ES-A2HS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b98efd19-482d-4671-bdc4-19ed9f884c19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ES-A2HS-11A (Solid Tissue Normal), aliquot TCGA-ES-A2HS-11A-11D-A183-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/095f7c09-7d33-4b5e-9c4e-e375f7b52169

The open-access MAF lists 87 somatic variants for this specimen: 57 protein-altering or splice-affecting, 24 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 24, Nonsense Mutation 4, Intron 3, Splice Site 3, In Frame Del 2, Frame Shift Ins 1, 3'Flank 1, Splice Region 1, Frame Shift Del 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.1694A>G p.Y565C | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67130061; called by muse, varscan2
- ADAT2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52794057; called by muse, mutect2, varscan2
- ALB | c.537delinsCC p.F180Lfs*4 | Frame Shift Ins (INS) | VAF 121/339 reads (36%) | catalogued as COSV55737426; called by pindel, varscan2*
- ALB | c.615+1G>A p.X205_splice | Splice Site (SNP) | VAF 37/132 reads (28%) | catalogued as COSV55737435; called by muse, varscan2
- AMMECR1L | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as COSV55760371, COSV99761271; called by muse, mutect2, varscan2
- AXIN1 | c.578T>A p.M193K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV51986072; called by muse, mutect2, varscan2
- CALB1 | c.620A>C p.D207A | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55367191; called by muse, mutect2, varscan2
- CDCP2 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV61283397; called by muse, mutect2, varscan2
- CEP295 | c.7357G>A p.V2453I | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV57347878; called by muse, mutect2, varscan2
- CFAP47 | c.5362G>C p.D1788H | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV57972997, COSV57976903; called by muse, mutect2
- CGNL1 | c.2325T>G p.D775E | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV55566197; called by muse, mutect2, varscan2
- CMTM4 | c.632A>T p.Y211F | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.347); catalogued as COSV58062547; called by muse, varscan2
- CUX1 | c.1391C>A p.S464Y | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as rs569218052, COSV52896498; called by muse, mutect2, varscan2
- ELAPOR1 | c.668C>A p.T223N | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV64044819; called by muse, mutect2, varscan2
- EPS8L3 | c.1397C>T p.P466L (on ENST00000361965 / NM_133181.4; = p.P436L on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV62609222; called by muse, mutect2, varscan2
- FMN2 | c.2548A>G p.K850E | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60417445; called by muse, mutect2, varscan2
- FOXP1 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770216660, COSV59539905; called by muse, varscan2
- GFRAL | c.893A>C p.Q298P | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs766549763, COSV61230218; called by muse, mutect2, varscan2
- GGTLC1 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53847316; called by muse, mutect2, varscan2
- GK5 | c.1545G>T p.W515C | Missense Mutation (SNP) | VAF 224/471 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67485587; called by muse, mutect2, varscan2
- GOSR2 | c.8G>A p.R3H (on ENST00000393456 / NM_001321134.1; = p.R21H on NM_004287.5) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs981608270, COSV56662090; called by muse, mutect2, varscan2
- IGFN1 | c.2297C>T p.A766V (on ENST00000295591 / NM_001367841.1; = p.A3223V on NM_001164586.2) | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); catalogued as COSV55170542, COSV99813487; called by muse, mutect2, varscan2
- INTS7 | c.2133A>T p.L711F | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as COSV65344110; called by muse, mutect2, varscan2
- ISLR | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV51433482; called by muse, mutect2, varscan2
- KALRN | c.6404A>G p.D2135G (on ENST00000360013 / NM_001024660.4; = p.D438G on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV52254577; called by muse, mutect2
- KCNV2 | c.1559T>G p.F520C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV66055906; called by muse, mutect2
- LIPC | c.944G>A p.S315N | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV54421818; called by muse, mutect2, varscan2
- LUC7L3 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 170/311 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV53586374; called by muse, mutect2, varscan2
- MAP1S | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV60722323; called by muse, mutect2, varscan2
- MEP1B | c.875C>G p.P292R | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.408); catalogued as COSV52496957; called by muse, mutect2, varscan2
- MST1R | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541331773, COSV56567665; called by muse, mutect2, varscan2
- PDHA2 | c.898C>A p.R300S | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776756344, COSV54778480, COSV54779576; called by muse, mutect2, varscan2
- PMEPA1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 33/97 reads (34%) | catalogued as COSV55692874, COSV55694999; called by muse, mutect2, varscan2
- POMT2 | c.1654G>T p.G552W | Missense Mutation (SNP) | VAF 80/154 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55070618; called by muse, mutect2, varscan2
- POMT2 | c.1654-1G>T p.X552_splice | Splice Site (SNP) | VAF 74/145 reads (51%) | catalogued as COSV55070629; called by muse, varscan2
- PPFIBP2 | c.2049C>G p.I683M | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55076176; called by muse, mutect2, varscan2
- PXDNL | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs936865843, COSV62476590; called by muse, mutect2
- RECQL4 | c.1382A>T p.Q461L | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV52878876; called by muse, mutect2
- SCUBE2 | c.1826G>T p.R609L | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV58541481, COSV58542026; called by muse, mutect2, varscan2
- SDK2 | c.6167G>A p.G2056E | Missense Mutation (SNP) | VAF 261/489 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV66184522; called by muse, mutect2, varscan2
- SGCB | c.853T>C p.Y285H | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV67340868; called by muse, mutect2, varscan2
- SHMT2 | c.237C>A p.F79L | Missense Mutation (SNP) | VAF 73/135 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61073714; called by muse, mutect2, varscan2
- TANGO6 | c.2126A>T p.Q709L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV55763740; called by muse, mutect2, varscan2
- TMEM214 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs375315795; called by muse, mutect2, varscan2
- TRIM46 | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58112956; called by muse, mutect2, varscan2
- VASH1 | c.399G>A p.Q133= | Splice Region (SNP) | VAF 91/329 reads (28%) | catalogued as COSV51335145, COSV51335768; called by muse, mutect2, varscan2
- VCL | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.174); catalogued as COSV53008450; called by muse, mutect2
- ZBTB32 | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as COSV52890154; called by muse, mutect2, varscan2
- ZNF284 | c.1351G>A p.G451R | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1189794700, COSV69690867; called by muse, mutect2, varscan2
- ZNF302 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV71063460; called by muse, mutect2, varscan2
- ZNF324 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 49/149 reads (33%) | catalogued as COSV52179624, COSV52180212; called by muse, mutect2, varscan2
- ZNF511 | c.554+1G>A p.X185_splice | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as rs773215223, COSV62919970; called by muse, mutect2, varscan2
- AXIN1 | c.999_1000del p.S334Pfs*16 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- GSDMB | c.240_242del p.K81del | In Frame Del (DEL) | VAF 103/191 reads (54%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- RBM10 | c.1606_1617del p.K536_L539del | In Frame Del (DEL) | VAF 33/40 reads (83%) | called by mutect2, pindel, varscan2
- XRN1 | c.1395G>A p.W465* | Nonsense Mutation (SNP) | VAF 93/358 reads (26%) | called by muse, varscan2
- ADGRV1 | c.5121G>A p.Q1707= | Silent (SNP) | VAF 40/51 reads (78%) | catalogued as rs1195132598, COSV67983250; called by muse, mutect2, varscan2
- ASAP1 | c.1641T>C p.Y547= | Silent (SNP) | VAF 69/243 reads (28%) | catalogued as rs749003615, COSV63047248; called by muse, mutect2, varscan2
- COG6 | c.1338C>T p.L446= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV62995571; called by muse, mutect2, varscan2
- DLEC1 | c.192C>T p.R64= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as COSV57298305; called by muse, mutect2, varscan2
- ERN2 | c.1576C>T p.L526= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV56832904; called by muse, mutect2, varscan2
- FOXO1 | c.558C>T p.I186= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as rs754690688, COSV65426277; called by muse, mutect2, varscan2
- HOMEZ | c.867T>C p.S289= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV62536770; called by muse, mutect2, varscan2
- MS4A4A | c.564G>A p.V188= | Silent (SNP) | VAF 86/421 reads (20%) | catalogued as COSV59700893; called by muse, mutect2, varscan2
- MS4A8 | c.525C>A p.A175= | Silent (SNP) | VAF 51/140 reads (36%) | catalogued as COSV55753859; called by muse, mutect2, varscan2
- PCDHB16 | c.903T>A p.V301= | Silent (SNP) | VAF 26/37 reads (70%) | catalogued as COSV53360991; called by muse, mutect2, varscan2
- PCSK2 | c.684A>T p.G228= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV52730546, COSV52745265; called by muse, mutect2, varscan2
- PKP2 | c.471G>A p.E157= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV50728987; called by muse, mutect2, varscan2
- PTPN5 | c.1113C>T p.A371= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs144666949; called by muse, mutect2, varscan2
- RBM10 | c.1599T>C p.A533= | Silent (SNP) | VAF 34/38 reads (89%) | called by mutect2, varscan2
- RCOR2 | c.922C>T p.L308= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV56849862; called by muse, mutect2, varscan2
- RIMBP3B | c.4623C>T p.A1541= | Silent (SNP) | VAF 195/980 reads (20%) | catalogued as COSV63115736; called by muse, mutect2, varscan2
- SEC14L6 | c.849C>G p.S283= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV67856777; called by muse, mutect2, varscan2
- SLC22A11 | c.160C>T p.L54= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs776086473, COSV57252714; called by muse, mutect2, varscan2
- SMG1 | c.8130G>A p.L2710= | Silent (SNP) | VAF 103/182 reads (57%) | catalogued as COSV67170712; called by muse, mutect2, varscan2
- SV2B | c.411G>A p.E137= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV57699368; called by muse, mutect2, varscan2
- TAP1 | c.654G>T p.G218= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as rs1173286127, COSV62754251; called by muse, mutect2, varscan2
- TSG101 | c.1116G>A p.Q372= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV52649465; called by muse, mutect2, varscan2
- WSB2 | c.1008G>C p.G336= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as COSV57477467; called by muse, mutect2
- ZNF208 | c.1809T>C p.H603= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as COSV68103702; called by muse, mutect2, varscan2
- ARL13A | c.*355G>C | 3'UTR (SNP) | VAF 71/296 reads (24%) | called by muse, mutect2, varscan2
- CSMD2 | c.6862+657A>G | Intron (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2, varscan2
- DHRS4L1 | n.177-455C>T | Intron (SNP) | VAF 124/288 reads (43%) | catalogued as rs373705961; called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46109897 G>T | 5'Flank (SNP) | VAF 51/127 reads (40%) | catalogued as rs559576610; called by muse, mutect2, varscan2
- MOV10L1 | c.2627+1300G>C | Intron (SNP) | VAF 77/183 reads (42%) | catalogued as COSV53174417; called by muse, mutect2, varscan2
- MUC2 | chr11:1094715 C>A | 3'Flank (SNP) | VAF 350/1463 reads (24%) | catalogued as rs749701488; called by muse, mutect2, varscan2
